Somatic mutation profile of cancer-model specimen HCM-CSHL-0057-C18-85B (3D Organoid; aliquot HCM-CSHL-0057-C18-85B-01D-A786-36), derived from the primary tumor of HCMI case HCM-CSHL-0057-C18, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IVA; Tumor grade: GB; Age at diagnosis: 68.4 years (24,973 days).
Specimen HCM-CSHL-0057-C18-85B: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: 3D Organoid; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5f7469b1-222b-45e3-accf-c3abaa5dedf2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-CSHL-0057-C18-10A (Blood Derived Normal), aliquot HCM-CSHL-0057-C18-10A-01D-A786-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2556778a-ab38-435d-85cf-b49acc0d4d78

The open-access MAF lists 129 somatic variants for this specimen: 87 protein-altering or splice-affecting, 29 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 71, Silent 29, Nonsense Mutation 6, Intron 4, 3'UTR 3, RNA 3, Frame Shift Del 3, Splice Site 3, Splice Region 2, 5'Flank 1, 5'UTR 1, In Frame Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- APC | c.2626C>T p.R876* | Nonsense Mutation (SNP) | VAF 188/188 reads (100%) | hotspot (GDC flag); catalogued as rs121913333, CM942020, COSV57320538; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- ADAMTS6 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 32/91 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758167428; called by muse, mutect2, varscan2
- ADGRB1 | c.1133C>T p.T378M | Missense Mutation (SNP) | VAF 96/469 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs774842173; called by muse, mutect2, varscan2
- ANKRD53 | c.397G>A p.E133K | Missense Mutation (SNP) | VAF 208/296 reads (70%) | SIFT tolerated (0.15); PolyPhen benign (0.221); catalogued as rs1553423084; called by muse, mutect2, varscan2
- ARHGAP28 | c.1212A>C p.K404N (on ENST00000383472 / NM_001366230.1; = p.K245N on NM_001010000.3) | Missense Mutation (SNP) | VAF 51/114 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51631599; called by muse, mutect2, varscan2
- CBY2 | c.280C>T p.R94C | Missense Mutation (SNP) | VAF 134/557 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as rs764889227, COSV100137847; called by muse, mutect2, varscan2
- CD69 | c.533A>G p.N178S | Missense Mutation (SNP) | VAF 8/112 reads (7%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV57302448; called by muse, mutect2
- CDH23 | c.3955G>A p.E1319K | Missense Mutation (SNP) | VAF 184/382 reads (48%) | SIFT tolerated (0.18); PolyPhen benign (0.03); catalogued as rs749805386, COSV56472692; called by muse, mutect2, varscan2
- CDK5RAP2 | c.1199G>A p.S400N | Missense Mutation (SNP) | VAF 60/670 reads (9%) | SIFT tolerated (0.97); PolyPhen benign (0); catalogued as rs1312128419, COSV62574841; called by muse, mutect2
- DCAF12L2 | c.1001C>T p.P334L | Missense Mutation (SNP) | VAF 221/221 reads (100%) | SIFT tolerated (0.58); PolyPhen benign (0); catalogued as rs1229366218, COSV63580270, COSV63581169; called by muse, mutect2, varscan2
- DOCK10 | c.4814G>A p.R1605Q | Missense Mutation (SNP) | VAF 29/88 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs772726138, COSV51418481; called by muse, mutect2, varscan2
- FAT4 | c.9685G>A p.A3229T | Missense Mutation (SNP) | VAF 10/116 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1461356168, COSV100629687; called by muse, mutect2
- FOLH1 | c.1624-2A>G p.X542_splice | Splice Site (SNP) | VAF 23/141 reads (16%) | catalogued as rs1186688438; called by muse, mutect2, varscan2
- GATA3 | c.605G>A p.R202H | Missense Mutation (SNP) | VAF 210/430 reads (49%) | SIFT tolerated (0.55); PolyPhen possibly damaging (0.8); catalogued as rs767671768, COSV60519223; called by muse, mutect2, varscan2
- HIP1 | c.1399C>T p.R467* | Nonsense Mutation (SNP) | VAF 153/673 reads (23%) | catalogued as rs782392081; called by muse, mutect2, varscan2
- HSPA12B | c.1312G>A p.V438M | Missense Mutation (SNP) | VAF 26/394 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.98); catalogued as rs1179549786; called by muse, mutect2
- KRT9 | c.1441A>T p.S481C | Missense Mutation (SNP) | VAF 150/262 reads (57%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.053); catalogued as COSV55852320; called by muse, mutect2, varscan2
- LRP8 | c.77_78insGCTGCGGCT p.L26_Q27insLRL | In Frame Ins (INS) | VAF 39/279 reads (14%) | catalogued as rs1553199822; called by pindel, varscan2
- LRRTM4 | c.247G>A p.G83S | Missense Mutation (SNP) | VAF 100/335 reads (30%) | SIFT tolerated (0.18); PolyPhen benign (0.057); catalogued as rs1289836030, COSV69138812, COSV69141526; called by muse, mutect2, varscan2
- MPP4 | c.671G>A p.R224Q | Missense Mutation (SNP) | VAF 81/275 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs370307780; called by muse, mutect2, varscan2
- MUSK | c.284G>A p.G95D | Missense Mutation (SNP) | VAF 23/236 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV51882513; called by muse, mutect2, varscan2
- MYO3A | c.2849G>A p.R950H | Missense Mutation (SNP) | VAF 25/308 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs143371522, COSV56338758; ClinVar: uncertain significance; called by muse, mutect2
- MYT1 | c.3308C>T p.P1103L | Missense Mutation (SNP) | VAF 231/409 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as rs377470537; called by muse, mutect2, varscan2
- NRXN1 | c.1526G>A p.R509H | Missense Mutation (SNP) | VAF 236/343 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs372823663; called by muse, mutect2, varscan2
- OBSCN | c.9490C>T p.R3164C | Missense Mutation (SNP) | VAF 50/116 reads (43%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.99); catalogued as rs369458693, COSV99486553; called by muse, mutect2, varscan2
- PDGFRA | c.2708C>A p.S903Y | Missense Mutation (SNP) | VAF 144/509 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV57272036; called by muse, mutect2, varscan2
- PEG3 | c.4639G>T p.E1547* | Nonsense Mutation (SNP) | VAF 14/262 reads (5%) | catalogued as COSV55641990; called by muse, mutect2
- PKHD1 | c.4687G>A p.G1563S | Missense Mutation (SNP) | VAF 317/513 reads (62%) | SIFT tolerated (0.38); PolyPhen benign (0.183); catalogued as COSV100583349; called by muse, mutect2, varscan2
- PLXNA2 | c.5632C>T p.R1878W | Missense Mutation (SNP) | VAF 102/262 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.857); catalogued as rs141651654; called by muse, mutect2, varscan2
- PRDM9 | c.1129C>T p.L377F | Missense Mutation (SNP) | VAF 275/302 reads (91%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs775142209, COSV57014387; called by muse, mutect2, varscan2
- RABL6 | c.943G>A p.G315S | Missense Mutation (SNP) | VAF 115/211 reads (55%) | SIFT tolerated (0.93); PolyPhen benign (0); catalogued as rs1437590053; called by muse, mutect2, varscan2
- RFXANK | c.485C>T p.S162L | Missense Mutation (SNP) | VAF 42/687 reads (6%) | SIFT tolerated (0.27); PolyPhen possibly damaging (0.868); catalogued as rs753776724; called by muse, mutect2
- RNASEL | c.1898C>T p.T633M | Missense Mutation (SNP) | VAF 162/326 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.88); catalogued as rs746370635, COSV100842660; called by muse, mutect2, varscan2
- SCUBE1 | c.1229G>A p.R410H | Missense Mutation (SNP) | VAF 25/66 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.206); catalogued as rs563690047, COSV62611479; called by muse, mutect2, varscan2
- SLC26A4 | c.1002G>T p.G334= | Splice Region (SNP) | VAF 73/300 reads (24%) | catalogued as COSV55916993; called by muse, mutect2, varscan2
- SLC5A2 | c.295G>C p.E99Q | Missense Mutation (SNP) | VAF 202/2188 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57891007, COSV57892278; called by muse, mutect2
- SLITRK2 | c.525C>A p.S175R | Missense Mutation (SNP) | VAF 10/163 reads (6%) | SIFT tolerated (0.43); PolyPhen benign (0.049); catalogued as COSV59423879; called by muse, mutect2
- SPAG17 | c.2157G>T p.Q719H | Missense Mutation (SNP) | VAF 14/137 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.267); catalogued as COSV100309590; called by muse, mutect2, varscan2
- SPRY3 | c.744C>A p.C248* | Nonsense Mutation (SNP) | VAF 121/527 reads (23%) | catalogued as rs1488405401; called by muse, mutect2, varscan2
- SPTBN2 | c.4885A>C p.K1629Q | Missense Mutation (SNP) | VAF 411/595 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs990233587; called by muse, mutect2, varscan2
- STK3 | c.919C>T p.R307* | Nonsense Mutation (SNP) | VAF 37/99 reads (37%) | catalogued as rs763527585, COSV101372443; called by muse, mutect2, varscan2
- TIAM1 | c.3654C>T p.D1218= | Splice Region (SNP) | VAF 64/134 reads (48%) | catalogued as rs375189386; called by muse, mutect2, varscan2
- TMEM221 | c.646C>T p.R216C | Missense Mutation (SNP) | VAF 48/104 reads (46%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as rs866472518; called by muse, mutect2, varscan2
- TTN | c.53189C>T p.S17730L (on ENST00000591111; = p.S10306L on NM_003319.4) | Missense Mutation (SNP) | VAF 14/51 reads (27%) | PolyPhen probably damaging (0.996); catalogued as COSV60386013; called by muse, mutect2, varscan2
- VPREB1 | c.62C>T p.P21L | Missense Mutation (SNP) | VAF 188/378 reads (50%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs372350881; called by muse, mutect2, varscan2
- APOB | c.8437C>T p.Q2813* | Nonsense Mutation (SNP) | VAF 86/235 reads (37%) | called by muse, mutect2, varscan2
- ARFGEF1 | c.5129G>T p.G1710V | Missense Mutation (SNP) | VAF 69/222 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- BLNK | c.1066G>T p.A356S | Missense Mutation (SNP) | VAF 30/468 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); called by muse, mutect2
- CCDC166 | c.277C>T p.R93W | Missense Mutation (SNP) | VAF 508/665 reads (76%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.877); called by muse, mutect2, varscan2
- CNNM1 | c.1148C>T p.A383V | Missense Mutation (SNP) | VAF 196/433 reads (45%) | SIFT tolerated (1); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- DPYSL2 | c.700G>A p.E234K | Missense Mutation (SNP) | VAF 37/208 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2, varscan2
- DSEL | c.1166C>G p.A389G | Missense Mutation (SNP) | VAF 20/240 reads (8%) | SIFT tolerated (0.39); PolyPhen benign (0.437); called by muse, mutect2
- ENPEP | c.232T>C p.C78R | Missense Mutation (SNP) | VAF 35/299 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPB41L5 | c.665A>G p.N222S | Missense Mutation (SNP) | VAF 41/71 reads (58%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- F8 | c.4875C>A p.S1625R | Missense Mutation (SNP) | VAF 50/173 reads (29%) | SIFT tolerated (0.17); PolyPhen benign (0.075); called by muse, mutect2, varscan2
- FAT4 | c.3626A>C p.K1209T | Missense Mutation (SNP) | VAF 38/79 reads (48%) | SIFT tolerated (0.32); PolyPhen benign (0.328); called by muse, mutect2, varscan2
- FOXD4L5 | c.890C>T p.P297L | Missense Mutation (SNP) | VAF 207/932 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.042); called by muse, mutect2, varscan2
- GPR137C | c.305C>T p.A102V | Missense Mutation (SNP) | VAF 46/530 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2
- GPR149 | c.1442C>A p.A481D | Missense Mutation (SNP) | VAF 86/165 reads (52%) | SIFT deleterious (0.04); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- IGF2BP1 | c.1349A>T p.K450I | Missense Mutation (SNP) | VAF 23/165 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- IGKV1-12 | c.269G>T p.G90V | Missense Mutation (SNP) | VAF 242/865 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); called by muse, mutect2, varscan2
- IGKV3OR2-268 | c.301C>A p.P101T | Missense Mutation (SNP) | VAF 49/553 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.426); called by muse, mutect2, varscan2
- IL6R | c.436G>A p.A146T | Missense Mutation (SNP) | VAF 166/500 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); called by muse, mutect2, varscan2
- ITGA5 | c.2493+1G>T p.X831_splice | Splice Site (SNP) | VAF 59/257 reads (23%) | called by muse, mutect2, varscan2
- JAKMIP3 | c.1300T>G p.L434V | Missense Mutation (SNP) | VAF 41/206 reads (20%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.99); called by muse, mutect2, varscan2
- KEL | c.1781G>T p.G594V | Missense Mutation (SNP) | VAF 147/1109 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); called by muse, mutect2, varscan2
- MAPK4 | c.1455G>T p.E485D | Missense Mutation (SNP) | VAF 8/31 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.48); called by muse, mutect2, varscan2
- MMRN1 | c.2656G>T p.V886F | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (0.07); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- MOK | c.17C>T p.A6V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- NCKAP1L | c.1700C>A p.A567D | Missense Mutation (SNP) | VAF 125/463 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- NEB | c.4601A>G p.N1534S | Missense Mutation (SNP) | VAF 22/74 reads (30%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.792); called by muse, mutect2, varscan2
- OVCH2 | c.1083T>A p.D361E | Missense Mutation (SNP) | VAF 81/271 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- PLG | c.892C>A p.H298N | Missense Mutation (SNP) | VAF 36/451 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.05); called by muse, mutect2
- PLPPR4 | c.277G>A p.V93I | Missense Mutation (SNP) | VAF 53/181 reads (29%) | SIFT tolerated (0.41); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PPID | c.8A>G p.H3R | Missense Mutation (SNP) | VAF 35/325 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.063); called by muse, mutect2, varscan2
- PSD | c.785del p.P262Hfs*32 | Frame Shift Del (DEL) | VAF 27/80 reads (34%) | called by mutect2, pindel, varscan2
- RYR2 | c.5415T>A p.H1805Q | Missense Mutation (SNP) | VAF 95/316 reads (30%) | SIFT deleterious (0.05); PolyPhen benign (0.067); called by muse, mutect2, varscan2
- SCG2 | c.1304A>G p.D435G | Missense Mutation (SNP) | VAF 50/142 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- SLCO1B1 | c.1310del p.G437Dfs*2 | Frame Shift Del (DEL) | VAF 13/108 reads (12%) | called by mutect2, pindel*
- SPTBN5 | c.2261C>T p.A754V | Missense Mutation (SNP) | VAF 97/283 reads (34%) | SIFT tolerated (0.56); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- STAB2 | c.82-2del p.X28_splice | Splice Site (DEL) | VAF 42/290 reads (14%) | called by mutect2, pindel*, varscan2
- SYNE1 | c.15025C>T p.L5009F (on ENST00000367255 / NM_182961.4; = p.L4938F on NM_033071.3) | Missense Mutation (SNP) | VAF 14/308 reads (5%) | SIFT tolerated (0.06); PolyPhen benign (0.204); called by muse, mutect2
- TEX10 | c.2417del p.Y806Ffs*6 | Frame Shift Del (DEL) | VAF 38/95 reads (40%) | called by mutect2, pindel, varscan2
- TP53 | c.757dup p.T253Nfs*11 | Frame Shift Ins (INS) | VAF 261/361 reads (72%) | called by mutect2, pindel, varscan2
- UMODL1 | c.2621C>T p.A874V (on ENST00000408910 / NM_001004416.2; = p.A1002V on NM_173568.3) | Missense Mutation (SNP) | VAF 133/286 reads (47%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- ZGRF1 | c.5428G>A p.E1810K | Missense Mutation (SNP) | VAF 32/136 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- ZHX1 | c.2348C>T p.A783V | Missense Mutation (SNP) | VAF 71/386 reads (18%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- AC011462.1 | c.897G>A p.R299= | Silent (SNP) | VAF 327/697 reads (47%) | catalogued as COSV99524413; called by muse, mutect2, varscan2
- BEST2 | c.312C>T p.D104= | Silent (SNP) | VAF 76/217 reads (35%) | called by muse, mutect2, varscan2
- BICDL1 | c.714C>T p.N238= | Silent (SNP) | VAF 87/335 reads (26%) | called by muse, mutect2, varscan2
- CCDC168 | c.5187G>A p.P1729= | Silent (SNP) | VAF 35/130 reads (27%) | catalogued as rs780744858, COSV70554779; called by muse, mutect2, varscan2
- COL5A2 | c.834G>T p.V278= | Silent (SNP) | VAF 32/225 reads (14%) | called by muse, mutect2, varscan2
- DNHD1 | c.10041C>T p.D3347= | Silent (SNP) | VAF 184/532 reads (35%) | catalogued as rs1415822771; called by muse, mutect2, varscan2
- FGD5 | c.1410G>T p.L470= | Silent (SNP) | VAF 124/256 reads (48%) | called by muse, mutect2, varscan2
- FREM1 | c.6231G>A p.A2077= | Silent (SNP) | VAF 73/137 reads (53%) | catalogued as rs148735553; called by muse, mutect2, varscan2
- ICE1 | c.1980T>A p.T660= | Silent (SNP) | VAF 41/79 reads (52%) | called by muse, mutect2, varscan2
- KBTBD11 | c.1578A>T p.R526= | Silent (SNP) | VAF 49/128 reads (38%) | catalogued as rs1285791077; called by muse, mutect2, varscan2
- KCNA1 | c.1062G>A p.S354= | Silent (SNP) | VAF 177/264 reads (67%) | catalogued as rs779989266, COSV66838312; called by muse, mutect2, varscan2
- MCM7 | c.381T>A p.P127= | Silent (SNP) | VAF 251/522 reads (48%) | called by muse, mutect2, varscan2
- MSLN | c.1131C>A p.L377= | Silent (SNP) | VAF 118/445 reads (27%) | called by muse, mutect2, varscan2
- MVP | c.1053C>T p.H351= | Silent (SNP) | VAF 121/526 reads (23%) | catalogued as rs1321673852; called by muse, mutect2, varscan2
- PCDH15 | c.4335G>A p.A1445= | Silent (SNP) | VAF 47/125 reads (38%) | catalogued as rs570557379, COSV57382499; called by muse, mutect2, varscan2
- PCDHB4 | c.924C>T p.F308= | Silent (SNP) | VAF 39/84 reads (46%) | catalogued as COSV52021508; called by muse, mutect2, varscan2
- PKD1 | c.1857G>A p.P619= | Silent (SNP) | VAF 232/333 reads (70%) | catalogued as rs749014917; called by muse, mutect2, varscan2
- POU2AF1 | c.372G>T p.V124= | Silent (SNP) | VAF 157/456 reads (34%) | called by muse, mutect2, varscan2
- RYR1 | c.2118C>T p.V706= | Silent (SNP) | VAF 103/243 reads (42%) | catalogued as rs769623563, COSV62103182; ClinVar: likely benign; called by muse, mutect2, varscan2
- SAMD15 | c.1521C>T p.F507= | Silent (SNP) | VAF 54/106 reads (51%) | catalogued as rs143386437; called by muse, mutect2, varscan2
- SRRM4 | c.504G>A p.R168= | Silent (SNP) | VAF 24/103 reads (23%) | called by muse, mutect2, varscan2
- SULF2 | c.768G>A p.P256= | Silent (SNP) | VAF 164/462 reads (35%) | catalogued as rs201684871, COSV100736945, COSV63414476; called by muse, mutect2, varscan2
- TBR1 | c.420C>T p.G140= | Silent (SNP) | VAF 25/336 reads (7%) | called by muse, mutect2
- THSD4 | c.165G>T p.V55= | Silent (SNP) | VAF 116/116 reads (100%) | called by muse, mutect2, varscan2
- TSHR | c.1047C>T p.N349= | Silent (SNP) | VAF 190/413 reads (46%) | catalogued as rs370857348; ClinVar: likely benign; called by muse, mutect2, varscan2
- TTN | c.9924C>A p.V3308= (on ENST00000591111; = p.V3262= on NM_003319.4) | Silent (SNP) | VAF 92/294 reads (31%) | catalogued as COSV60011163, COSV60180903; called by muse, mutect2, varscan2
- UBE2O | c.3042C>T p.A1014= | Silent (SNP) | VAF 62/115 reads (54%) | catalogued as rs150733080; called by muse, mutect2, varscan2
- WDR36 | c.1011C>T p.A337= | Silent (SNP) | VAF 80/179 reads (45%) | called by muse, mutect2, varscan2
- ZSCAN18 | c.459C>T p.Y153= | Silent (SNP) | VAF 15/185 reads (8%) | catalogued as rs199638300; called by muse, mutect2
- ACAD8 | c.705+92A>T | Intron (SNP) | VAF 14/302 reads (5%) | called by muse, mutect2
- AL163540.1 | n.163A>T | RNA (SNP) | VAF 25/107 reads (23%) | called by muse, mutect2, varscan2
- BMERB1 | chr16:15591058 C>A | 3'Flank (SNP) | VAF 43/340 reads (13%) | called by muse, mutect2, varscan2
- CFAP46 | c.660+27C>T | Intron (SNP) | VAF 66/146 reads (45%) | catalogued as rs753676161; called by muse, mutect2, varscan2
- CORT | c.-62C>T | 5'UTR (SNP) | VAF 31/84 reads (37%) | called by muse, mutect2, varscan2
- KRT8P11 | n.545G>A | RNA (SNP) | VAF 105/230 reads (46%) | catalogued as rs762050968; called by muse, mutect2, varscan2
- MATR3 | c.*2144G>C | 3'UTR (SNP) | VAF 133/133 reads (100%) | called by muse, mutect2, varscan2
- PERM1 | chr1:981152 G>A | 5'Flank (SNP) | VAF 84/179 reads (47%) | catalogued as rs373197642; called by muse, mutect2, varscan2
- PKD1L2 | n.853G>A | RNA (SNP) | VAF 156/157 reads (99%) | catalogued as rs772490214; called by muse, mutect2, varscan2
- RAB11FIP3 | c.1265+2223G>T | Intron (SNP) | VAF 79/180 reads (44%) | called by muse, mutect2, varscan2
- SFSWAP | c.*4G>A | 3'UTR (SNP) | VAF 76/345 reads (22%) | catalogued as rs191498396; called by muse, mutect2, varscan2
- TMPRSS11F | c.1015+1730G>T | Intron (SNP) | VAF 35/143 reads (24%) | called by muse, mutect2, varscan2
- XIAP | c.*2820A>G | 3'UTR (SNP) | VAF 128/129 reads (99%) | catalogued as rs774722477; called by muse, mutect2, varscan2
